Somatic mutation profile of tumor specimen 0DMEUH from CCDI case PBCALS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (493 days).
Specimen 0DMEUH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c1a59d2-9dfe-44bc-bf23-36cdeec9ea89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMEUL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2073ddd2-d188-4684-8a37-b1aeebc54c2b

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTTNBP2NL | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369269019; called by muse, mutect2
- NPAP1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs1295604109, COSV61512963; called by muse, mutect2, varscan2
- PRAMEF2 | c.570G>A p.T190= | Silent (SNP) | VAF 36/557 reads (6%) | catalogued as rs755821420, COSV53575202; called by muse, mutect2
